Gene-level copy-number profile of tumor specimen TCGA-CV-7242-01A from TCGA case TCGA-CV-7242, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.6 years (22,136 days).
Specimen TCGA-CV-7242-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e2d43297-38b5-4bb7-a9a0-4fe23ad33d05.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7242-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5b7db56d-662f-4890-94e0-aac297bed43e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 517; copy number 2: 13,346; copy number 3: 4,447; copy number 4: 38,590; copy number 5: 1,182; copy number 6: 1,614; copy number 11: 53; copy number 17: 34; copy number 36: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7242-01A-11D-2010-01): tumor purity 0.5, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 119 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,933,699–56,578,866, 66 genes, copy number 17–36 (broad region; genes not listed).
- chr15:19,878,555–20,940,333, 52 genes, copy number 11: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7, IGHD5OR15-5A, IGHD4OR15-4A, IGHD3OR15-3A, IGHD2OR15-2A, IGHD1OR15-1A, FAM30B, AC127381.1, BCAR1P1, RN7SL584P, AC087386.1, AC087386.2, BMS1P15, RHPN2P1, CHEK2P2, AC026495.2, AC026495.1, HERC2P3, AC023310.1, GOLGA6L6, AC023310.3, GOLGA8CP, RN7SL759P, SPATA31E2P, AC023310.2, IGHV1OR15-6, AC023310.4, NBEAP1, AC131280.1, AC012414.4, RNU6-498P, AC012414.2, AC012414.3, LONRF2P3, AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P, AC012414.5, AC037471.2, ZNF519P2, NF1P1, MIR5701-1.
- chr15:20,960,675–20,961,581, 1 gene, copy number 11: OR11J2P.

Autosomal genes at a single copy (total copy number 1): 517. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
